Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A954, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A954-01A (Primary Tumor).

(MM/DD/YYYY)

ICD O-3
Carcinoma, squamous cell NOS
Site Cervix NOS
8070/3
C53.9
JW 3/12/14

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

Product of biopsy of the uterine cervix:

. Moderately differentiated squamous cell carcinoma, invasive, associated with intense desmoplasia.

Source: NCI Genomic Data Commons file 5764d230-47eb-4ef6-9477-219d406917d8 (TCGA-VS-A954.5A62ACAB-9170-49CB-AA5A-82E90CA3A200.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).